CCDI case PBCCIM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0d16affb-3b6d-4a99-95e4-a6f01607c553

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,242 days).

Biospecimens (3 samples)
- Sample 0DOLVW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOQGK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOQGO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
